Surgical pathology report (de-identified scan), TCGA case TCGA-61-2008, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2008-02A (Recurrent Tumor).

FINAL DIAGNOSIS:

SOFT TISSUE, "RECURRENT TUMOR", EXCISION -
RECURRENT HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA (see comment).

COMMENT:

The current specimen was compared with the previous salpingo-oophorectomy specimen [REDACTED] showed morphologically identical tumor cells.

The concurrent pelvic wash [REDACTED] is positive for malignant cells.

ICD-O-3 Neovagina

adenocarcinoma, serous, NOS 8441/3

Site: pelvis - soft tissue C49.5

Pathologist:

** Report Electronically Signed Out **

By Pathologist:

fw
2/12/15

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

Source: NCI Genomic Data Commons file 324e1eb4-dae2-426c-806c-0fe21942d04b (TCGA-61-2008.614D7B6A-B3B4-4F1B-9762-0749D559247F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).